Somatic mutation profile of tumor specimen TCGA-EE-A20H-06A (aliquot TCGA-EE-A20H-06A-11D-A197-08) from TCGA case TCGA-EE-A20H, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 69.3 years (25,314 days).
Specimen TCGA-EE-A20H-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02b271ca-4f78-4861-b68f-cbf3a25ceb0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A20H-10A (Blood Derived Normal), aliquot TCGA-EE-A20H-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97453109-fbcb-4ef3-9db1-b2c84879e80a

The open-access MAF lists 723 somatic variants for this specimen: 483 protein-altering or splice-affecting, 221 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 449, Silent 221, Nonsense Mutation 18, Intron 10, Splice Region 6, RNA 6, Splice Site 5, Frame Shift Del 3, 5'UTR 2, 3'UTR 1, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB11 | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 63/127 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs760750012, CM067618, COSV55599241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 115/118 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 115/118 reads (97%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1300-1G>A p.X434_splice (on ENST00000521381 / NM_181523.3; = p.X164_splice on NM_181504.4) | Splice Site (SNP) | VAF 15/21 reads (71%) | hotspot (GDC flag); catalogued as COSV57135007, COSV99160385; called by muse, varscan2
- THSD7B | c.1670G>A p.G557E | Missense Mutation (SNP) | VAF 22/51 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as COSV55689123, COSV55699747; called by muse, mutect2, varscan2
- AASS | c.1021G>A p.G341S | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV62791511; called by muse, mutect2, varscan2
- ABCA13 | c.13151G>A p.G4384E | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as COSV68946889; called by muse, mutect2, varscan2
- ABCB5 | c.2939A>T p.K980I (on ENST00000404938 / NM_001163941.2; = p.K535I on NM_178559.6) | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV51719099; called by muse, mutect2, varscan2
- ABCC9 | c.2347G>A p.A783T | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.05); catalogued as COSV53966763, COSV53983760; called by muse, mutect2, varscan2
- ABRA | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 83/115 reads (72%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs773733534, COSV61733411; called by muse, mutect2, varscan2
- ACSM2A | c.1128G>A p.M376I (on ENST00000219054; = p.M297I on NM_001308169.2) | Missense Mutation (SNP) | VAF 79/268 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as COSV54584974; called by muse, mutect2
- ACSM2B | c.1271C>T p.S424F | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV61659722; called by muse, mutect2, varscan2
- ACSM2B | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs757950871, COSV61656530; called by muse, mutect2, varscan2
- ACY3 | c.292C>A p.Q98K | Missense Mutation (SNP) | VAF 76/130 reads (58%) | SIFT tolerated (0.21); PolyPhen benign (0.172); catalogued as COSV54830077; called by muse, varscan2
- ADAM11 | c.1727C>T p.T576M | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs370482564, COSV52349463; called by muse, mutect2, varscan2
- ADAM18 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); catalogued as rs374296414; called by muse, mutect2, varscan2
- ADAM23 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 76/182 reads (42%) | SIFT tolerated (0.82); PolyPhen benign (0.038); catalogued as COSV52214375, COSV52228039; called by muse, varscan2
- ADAMTS20 | c.3055G>A p.E1019K | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.841); catalogued as COSV67128809, COSV67131706; called by muse, mutect2, varscan2
- ADGRL4 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 34/35 reads (97%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs764619199, COSV66059595; called by muse, mutect2, varscan2
- AGBL2 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs370614257; called by muse, mutect2, varscan2
- AGBL2 | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100102197; called by muse, mutect2, varscan2
- AIP | c.442C>T p.L148F | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54161724; called by muse, mutect2, varscan2
- ALOX12B | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.85); PolyPhen benign (0.027); catalogued as rs536446862, COSV59874293, COSV59875704; called by muse, mutect2, varscan2
- ANKAR | c.1203+1G>A p.X401_splice | Splice Site (SNP) | VAF 35/68 reads (51%) | catalogued as COSV55617345; called by muse, mutect2, varscan2
- ANO1 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV60288666; called by muse, mutect2, varscan2
- ANXA6 | c.1211C>T p.T404I | Missense Mutation (SNP) | VAF 43/45 reads (96%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as rs769535547, COSV62908113; called by muse, mutect2, varscan2
- AOAH | c.1090G>T p.A364S | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV51746605, COSV51749660; called by muse, mutect2, varscan2
- AP002512.3 | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV54408576; called by muse, mutect2, varscan2
- APOB | c.1658C>T p.S553F | Missense Mutation (SNP) | VAF 228/507 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV51928677, COSV51949880; called by muse, mutect2, varscan2
- APOC3 | c.180G>A p.R60= | Splice Region (SNP) | VAF 91/117 reads (78%) | catalogued as rs760769978, COSV52636721; called by muse, mutect2, varscan2
- AREG | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs1219113338; called by muse, mutect2, varscan2
- ARFGEF3 | c.5773T>A p.C1925S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99294853; called by muse, mutect2, varscan2
- ARFGEF3 | c.5774G>C p.C1925S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99294854; called by muse, mutect2, varscan2
- ARHGAP39 | c.2021C>T p.P674L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.637); catalogued as COSV52775166; called by muse, mutect2, varscan2
- ARID1A | c.1140A>G p.P380= | Splice Region (SNP) | VAF 62/69 reads (90%) | catalogued as COSV61387474; called by muse, mutect2, varscan2
- ARID5A | c.1198C>T p.H400Y | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as rs1210775969, COSV62591729; called by muse, mutect2, varscan2
- ARPP21 | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV51806806; called by muse, mutect2, varscan2
- ASGR2 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.377); catalogued as rs866477035, COSV54689893; called by muse, mutect2, varscan2
- ASXL3 | c.5507G>A p.G1836E | Missense Mutation (SNP) | VAF 151/239 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52477534; called by muse, mutect2, varscan2
- ATP10D | c.1325C>T p.T442I | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56712445; called by muse, mutect2, varscan2
- ATP12A | c.1449G>A p.M483I | Missense Mutation (SNP) | VAF 75/110 reads (68%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV54522029; called by muse, mutect2, varscan2
- ATP8A1 | c.1947G>A p.K649= | Splice Region (SNP) | VAF 9/43 reads (21%) | catalogued as COSV52546272; called by muse, mutect2, varscan2
- ATP8A2 | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 51/229 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54972647; called by muse, mutect2, varscan2
- ATP8B2 | c.3386C>T p.S1129F (on ENST00000672630; = p.S1096F on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV100874508, COSV63833526; called by muse, mutect2, varscan2
- ATXN2 | c.892A>G p.S298G (on ENST00000550104; = p.S138G on NM_002973.4) | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT tolerated (0.22); PolyPhen benign (0.138); catalogued as COSV66485738; called by muse, mutect2, varscan2
- B3GLCT | c.760C>T p.H254Y | Missense Mutation (SNP) | VAF 61/88 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as rs776965440, COSV58458001; called by muse, mutect2, varscan2
- BCAN | c.2534G>C p.R845P | Missense Mutation (SNP) | VAF 151/162 reads (93%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV61259205; called by muse, mutect2, varscan2
- BDKRB2 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV60016728; called by muse, mutect2, varscan2
- BIRC7 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as COSV99417028; called by muse, mutect2, varscan2
- BIRC7 | c.576C>T p.S192= | Splice Region (SNP) | VAF 52/128 reads (41%) | catalogued as rs756051104, COSV99417032; called by muse, mutect2, varscan2
- BNC1 | c.2371T>A p.F791I | Missense Mutation (SNP) | VAF 68/131 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV61758932; called by muse, mutect2, varscan2
- BRINP3 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 71/74 reads (96%) | SIFT tolerated (0.23); PolyPhen benign (0.147); catalogued as rs375567534, COSV66538726; called by muse, mutect2, varscan2
- BRS3 | c.772C>T p.H258Y | Missense Mutation (SNP) | VAF 19/20 reads (95%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as COSV65711259; called by muse, mutect2, varscan2
- BSN | c.3935C>T p.T1312I | Missense Mutation (SNP) | VAF 53/64 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56526117; called by muse, mutect2, varscan2
- C14orf39 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.08); catalogued as COSV58784601; called by muse, mutect2, varscan2
- C21orf62 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV66672630; called by muse, mutect2, varscan2
- C4A | c.3346T>C p.S1116P | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as rs1291425411, COSV71178795; called by muse, mutect2, varscan2
- C8B | c.534G>A p.G178= | Splice Region (SNP) | VAF 70/77 reads (91%) | catalogued as COSV64777626; called by muse, mutect2, varscan2
- C9 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 102/285 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54680750; called by muse, mutect2, varscan2
- CA10 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 203/415 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.563); catalogued as COSV53341871; called by muse, mutect2, varscan2
- CAD | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV53031208; called by muse, mutect2, varscan2
- CADM2 | c.707C>T p.P236L (on ENST00000407528 / NM_001167674.2; = p.P238L on NM_153184.4) | Missense Mutation (SNP) | VAF 82/207 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV67399679; called by muse, mutect2, varscan2
- CALB1 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV55369102; called by muse, varscan2
- CAMK2G | c.751C>T p.Q251* | Nonsense Mutation (SNP) | VAF 42/45 reads (93%) | catalogued as rs574207682, COSV59485147, COSV59485889; called by muse, mutect2, varscan2
- CARD11 | c.1289A>G p.N430S | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV67801955; called by muse, mutect2, varscan2
- CASP8AP2 | c.2422C>T p.P808S | Missense Mutation (SNP) | VAF 77/88 reads (88%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as COSV52749536; called by muse, mutect2, varscan2
- CC2D1A | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.074); catalogued as COSV58785898; called by muse, mutect2, varscan2
- CCDC102B | c.1441G>A p.D481N | Missense Mutation (SNP) | VAF 65/70 reads (93%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV60134557; called by muse, mutect2, varscan2
- CCDC141 | c.1963A>T p.N655Y | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs1302927922, COSV55381005; called by muse, mutect2, varscan2
- CCP110 | c.1732G>T p.D578Y | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV66817989; called by muse, mutect2, varscan2
- CD33 | c.773T>C p.V258A | Missense Mutation (SNP) | VAF 52/89 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.182); catalogued as COSV51804308; called by muse, mutect2, varscan2
- CDCA7L | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100650944, COSV62261312; called by muse, mutect2, varscan2
- CDH18 | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 182/331 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV56955172; called by muse, mutect2, varscan2
- CDH18 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV56955183, COSV99939264; called by muse, mutect2, varscan2
- CERS5 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV58190035, COSV58190237; called by muse, mutect2, varscan2
- CES1 | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1278606700, COSV62085601; called by muse, mutect2, varscan2
- CETP | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.577); catalogued as COSV52362321; called by muse, mutect2, varscan2
- CHL1 | c.3614C>T p.P1205L (on ENST00000397491 / NM_001253387.1; = p.P1221L on NM_006614.4) | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99852543; called by muse, mutect2, varscan2
- CHRM3 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 65/148 reads (44%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV55101421; called by muse, mutect2, varscan2
- CLRN2 | c.523C>T p.L175F | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT tolerated (0.29); PolyPhen benign (0.037); catalogued as rs766803343, COSV71825269; called by muse, mutect2, varscan2
- CNGA4 | c.722A>T p.E241V | Missense Mutation (SNP) | VAF 53/92 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV66006925; called by muse, mutect2, varscan2
- CNGB3 | c.1771G>A p.G591R | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60697128; called by muse, mutect2, varscan2
- CNTN4 | c.98G>T p.S33I | Missense Mutation (SNP) | VAF 99/246 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.71); catalogued as rs748853919, COSV68589455; called by muse, mutect2, varscan2
- COL22A1 | c.4091C>T p.P1364L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV57356658; called by muse, mutect2
- COL4A3 | c.679G>A p.G227R | Missense Mutation (SNP) | VAF 66/70 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67419420; called by muse, mutect2, varscan2
- COL8A1 | c.2134G>A p.D712N | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53734882; called by muse, mutect2, varscan2
- CPAMD8 | c.3436T>C p.Y1146H (on ENST00000651564; = p.Y1099H on NM_015692.5) | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.964); catalogued as COSV71597304; called by muse, mutect2, varscan2
- CPAMD8 | c.754T>C p.F252L (on ENST00000651564; = p.F205L on NM_015692.5) | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV52239151; called by muse, mutect2, varscan2
- CPD | c.2962C>T p.R988C | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs760977698, COSV56711796; called by muse, mutect2, varscan2
- CPE | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 107/255 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as rs138641684; called by muse, mutect2, varscan2
- CR1 | c.2261T>C p.L754P | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.991); catalogued as COSV100888080; called by mutect2, varscan2
- CSMD1 | c.3332G>A p.G1111E (on ENST00000520002; = p.G1110E on NM_033225.6) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1563296664, COSV59360550; called by muse, mutect2, varscan2
- CT83 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 96/102 reads (94%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as COSV64141432; called by muse, mutect2, varscan2
- CUTC | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 41/47 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50013068; called by muse, mutect2, varscan2
- CYP2A7 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 75/114 reads (66%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV52499541; called by muse, mutect2, varscan2
- CYYR1 | c.230T>C p.I77T | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as rs781120830, COSV54836995; called by muse, mutect2
- DBX1 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs1000434461, COSV57054047; called by muse, mutect2, varscan2
- DCAF12L2 | c.1225G>A p.G409S | Missense Mutation (SNP) | VAF 106/108 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63583958; called by muse, mutect2, varscan2
- DCLK2 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV56198611; called by muse, varscan2
- DENND6B | c.1568A>G p.E523G | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.026); catalogued as COSV63784079; called by muse, mutect2, varscan2
- DLG2 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 39/45 reads (87%) | SIFT tolerated (0.87); PolyPhen benign (0.03); catalogued as COSV54679067; called by muse, mutect2, varscan2
- DLL3 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.468); catalogued as rs867150466, COSV52696458; called by muse, mutect2, varscan2
- DMD | c.8938-1G>A p.X2980_splice | Splice Site (SNP) | VAF 48/54 reads (89%) | catalogued as COSV58946520; called by muse, mutect2, varscan2
- DNAH10 | c.10765A>C p.T3589P (on ENST00000409039; = p.T3528P on NM_207437.3) | Missense Mutation (SNP) | VAF 30/35 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV69000134; called by muse, mutect2, varscan2
- DNAH11 | c.8534G>A p.R2845Q | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs372633683, COSV100179874; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH3 | c.6206C>T p.P2069L | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1391823180, COSV54511237; called by muse, mutect2, varscan2
- DNAH3 | c.3660G>A p.M1220I | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.919); catalogued as rs745513119, COSV54546901; called by muse, mutect2, varscan2
- DNAH5 | c.10421C>T p.T3474I | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV54247863, COSV54259710; called by muse, mutect2, varscan2
- DNAH5 | c.9395C>T p.S3132F | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV54215442; called by muse, mutect2, varscan2
- DNAH5 | c.8976G>A p.M2992I | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as COSV54247879, COSV99447701; called by muse, mutect2, varscan2
- DNAH6 | c.2345C>T p.S782F | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as COSV52854807; called by muse, mutect2, varscan2
- DNAH7 | c.8167C>T p.P2723S | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.752); catalogued as COSV56782139; called by muse, mutect2, varscan2
- DNER | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 41/44 reads (93%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV100520089, COSV59174681; called by muse, mutect2, varscan2
- DOHH | c.180C>G p.Y60* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as COSV51745975; called by muse, mutect2, varscan2
- DSC2 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV51868483; called by muse, mutect2, varscan2
- DSG3 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 53/88 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs774736138, COSV57124224; called by muse, mutect2, varscan2
- DSG3 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57129194; called by muse, mutect2, varscan2
- DSG4 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1385009281, COSV57396805; called by muse, mutect2, varscan2
- DSP | c.6688C>T p.P2230S | Missense Mutation (SNP) | VAF 74/115 reads (64%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV65795287; called by muse, mutect2, varscan2
- DSTYK | c.802A>T p.I268F | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV65688249; called by muse, mutect2
- DVL3 | c.1991C>T p.P664L | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.092); catalogued as COSV53049980; called by muse, mutect2, varscan2
- DYNC1LI2 | c.779G>A p.R260K | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.81); PolyPhen benign (0.006); catalogued as COSV99263296; called by muse, mutect2, varscan2
- DYSF | c.1398G>A p.W466* | Nonsense Mutation (SNP) | VAF 59/112 reads (53%) | catalogued as rs141400095; called by muse, mutect2, varscan2
- ELL2 | c.1517C>T p.S506F | Missense Mutation (SNP) | VAF 49/57 reads (86%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV52984888; called by muse, mutect2, varscan2
- ELMO1 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs1205672205, COSV60321291; called by muse, mutect2, varscan2
- ELOVL4 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 65/72 reads (90%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV63954595; called by muse, mutect2, varscan2
- ENHO | c.121G>A p.V41I | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs374481766; called by muse, mutect2, varscan2
- EPHA4 | c.835G>A p.G279R | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as rs1457488118, COSV56036454, COSV56042772; called by muse, mutect2, varscan2
- ERBB4 | c.2428G>A p.E810K | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV61476486, COSV61480579; called by muse, mutect2, varscan2
- ESRP1 | c.1979C>T p.T660I | Missense Mutation (SNP) | VAF 121/222 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs746129950, COSV64412332; called by muse, mutect2, varscan2
- EXOC7 | c.1760C>T p.S587F (on ENST00000335146 / NM_001145297.4; = p.S505F on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/151 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs868134546, COSV58037650; called by muse, mutect2, varscan2
- EYA1 | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58160674; called by muse, mutect2, varscan2
- EYA4 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); catalogued as COSV62059291; called by muse, mutect2, varscan2
- FAM155A | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as COSV65562911, COSV65580579; called by muse, mutect2, varscan2
- FAM47A | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.653); catalogued as rs1362509719, COSV60493840; called by muse, mutect2, varscan2
- FAT4 | c.7523C>T p.S2508L | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs267600010, COSV58702558; called by muse, varscan2
- FAT4 | c.10223T>C p.L3408P | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs549805956, COSV58704961; called by muse, mutect2, varscan2
- FAT4 | c.10898G>A p.G3633E | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58704979; called by muse, mutect2, varscan2
- FAT4 | c.12923C>T p.T4308I | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.206); catalogued as COSV58705003; called by muse, mutect2, varscan2
- FBXO47 | c.55C>A p.R19S | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV65242727; called by muse, mutect2, varscan2
- FLAD1 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT tolerated (0.8); PolyPhen benign (0.158); catalogued as COSV52699665; called by muse, mutect2, varscan2
- FMN2 | c.2911C>T p.P971S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.27); catalogued as rs778896753, COSV60421934, COSV60450150; called by muse, mutect2, varscan2
- FMN2 | c.5099G>A p.G1700E | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.043); catalogued as COSV60420981; called by muse, mutect2, varscan2
- FMO2 | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 261/282 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV52946669; called by muse, mutect2, varscan2
- FUT6 | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 64/107 reads (60%) | catalogued as COSV54608048; called by muse, mutect2, varscan2
- FUT8 | c.1337C>T p.S446L (on ENST00000360689 / NM_001371534.1; = p.S283L on NM_004480.4) | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as COSV61290270; called by muse, mutect2, varscan2
- GABRA1 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 83/92 reads (90%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV50099171, COSV99195678; called by muse, mutect2, varscan2
- GABRA4 | c.1000C>T p.L334F | Missense Mutation (SNP) | VAF 45/73 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51934094; called by muse, mutect2, varscan2
- GABRG1 | c.800G>A p.S267N | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV54950203; called by muse, mutect2, varscan2
- GALNT13 | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101224395, COSV67216396; called by muse, mutect2, varscan2
- GDA | c.49T>C p.F17L | Missense Mutation (SNP) | VAF 21/21 reads (100%) | SIFT tolerated (0.42); PolyPhen benign (0.026); catalogued as rs1406091698, COSV52997002; called by muse, mutect2, varscan2
- GDAP2 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 24/26 reads (92%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as rs148217136; called by muse, mutect2, varscan2
- GDF2 | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 25/26 reads (96%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as rs782199559; called by muse, mutect2, varscan2
- GFPT2 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV53811846; called by muse, mutect2, varscan2
- GHR | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1009695851, COSV50116549; called by muse, varscan2
- GHR | c.1661C>T p.S554L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.626); catalogued as COSV50127068; called by muse, mutect2, varscan2
- GJD2 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 84/176 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.461); catalogued as COSV51750347; called by muse, mutect2
- GLRB | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.962); catalogued as COSV52415619; called by muse, mutect2, varscan2
- GPR158 | c.3118C>T p.P1040S | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as COSV66265748, COSV66280641; called by muse, mutect2, varscan2
- GPR45 | c.655C>T p.L219F | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as rs769899916, COSV51525918; called by muse, mutect2, varscan2
- GPX5 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 89/289 reads (31%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as COSV69079809; called by muse, mutect2, varscan2
- GPX6 | c.289T>A p.L97M | Missense Mutation (SNP) | VAF 94/140 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62658874; called by muse, mutect2, varscan2
- GRIK2 | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 59/63 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59765142; called by muse, mutect2, varscan2
- GRIK3 | c.2096C>T p.S699F | Missense Mutation (SNP) | VAF 13/13 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66145798; called by muse, mutect2, varscan2
- GRIN2A | c.3466G>A p.E1156K | Missense Mutation (SNP) | VAF 83/193 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV58026228; called by muse, mutect2, varscan2
- GRIN3A | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 33/37 reads (89%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs145326290, COSV62450102; called by muse, mutect2, varscan2
- GUCY1A1 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56655746; called by muse, mutect2, varscan2
- HACL1 | c.1180G>A p.V394M | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs370023923; called by muse, mutect2, varscan2
- HHIPL2 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 251/566 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs903799033, COSV58565147; called by muse, mutect2, varscan2
- HMCN1 | c.4870G>A p.A1624T | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54935036; called by muse, mutect2, varscan2
- IFI27 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs771278257, COSV54140859; called by mutect2, varscan2
- IKZF2 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 89/181 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.242); catalogued as rs867718948, COSV59583273, COSV59584006; called by muse, mutect2, varscan2
- IL18R1 | c.1381C>T p.H461Y | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs952165884, COSV52126946; called by muse, mutect2, varscan2
- IL3 | c.175C>T p.L59F | Missense Mutation (SNP) | VAF 53/58 reads (91%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV57309288; called by muse, mutect2, varscan2
- IL37 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 71/157 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54490988; called by muse, mutect2, varscan2
- ILDR1 | c.911C>T p.P304L (on ENST00000344209 / NM_001199799.2; = p.P260L on NM_175924.4) | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV56553280; called by muse, varscan2
- IMPG2 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.756); catalogued as COSV51984498; called by muse, mutect2, varscan2
- ITFG1 | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 25/65 reads (38%) | catalogued as COSV57754549; called by muse, mutect2, varscan2
- ITPRIPL2 | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 118/260 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV67348049; called by muse, mutect2, varscan2
- KATNB1 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV65561771; called by muse, mutect2
- KCNA6 | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV54977250; called by muse, mutect2
- KCNA6 | c.731G>T p.G244V | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV54976571, COSV54977259; called by muse, mutect2
- KCNB1 | c.2057C>T p.P686L | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV65566561; called by muse, mutect2, varscan2
- KCNH5 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.088); catalogued as COSV59770859; called by muse, mutect2, varscan2
- KCNH7 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV59800205; called by muse, mutect2, varscan2
- KCNJ2 | c.923C>T p.T308M | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748053853, COSV54660057; called by muse, mutect2, varscan2
- KCNK9 | c.799A>T p.N267Y | Missense Mutation (SNP) | VAF 44/73 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV57281838; called by muse, mutect2, varscan2
- KIAA1328 | c.1049G>A p.G350E | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54463720; called by muse, mutect2, varscan2
- KIF16B | c.785C>T p.T262I | Missense Mutation (SNP) | VAF 91/193 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61713021; called by muse, mutect2, varscan2
- KIR3DL3 | c.464T>G p.L155R | Missense Mutation (SNP) | VAF 96/168 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52550786; called by muse, mutect2, varscan2
- KLHL13 | c.97A>G p.I33V | Missense Mutation (SNP) | VAF 53/59 reads (90%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.456); catalogued as rs1187274227, COSV53247464, COSV99452649; called by muse, mutect2, varscan2
- KLHL18 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 58/61 reads (95%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV51748268; called by muse, mutect2, varscan2
- KLHL20 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 62/114 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs747822376, COSV52944669; called by muse, mutect2, varscan2
- KMT2D | c.16405C>T p.P5469S | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99986320; called by muse, mutect2, varscan2
- KNOP1 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 91/181 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.54); catalogued as rs370890506; called by muse, mutect2, varscan2
- KYNU | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51589023; called by muse, mutect2, varscan2
- LAMA4 | c.2966C>T p.S989F (on ENST00000230538 / NM_001105206.3; = p.S982F on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/30 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as COSV57903843; called by muse, mutect2, varscan2
- LAMC2 | c.1481A>G p.E494G | Missense Mutation (SNP) | VAF 74/139 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51459185; called by muse, mutect2, varscan2
- LAT | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.01); catalogued as COSV57956799; called by muse, mutect2, varscan2
- LATS2 | c.2552G>A p.G851E | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as COSV66879182; called by muse, mutect2, varscan2
- LCT | c.3823G>A p.G1275R | Missense Mutation (SNP) | VAF 100/219 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs540136979, COSV51546366; called by muse, mutect2, varscan2
- LILRB4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 59/96 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.676); catalogued as COSV54406647; called by muse, mutect2, varscan2
- LMBR1L | c.1437C>A p.F479L | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated (0.78); PolyPhen benign (0.05); catalogued as COSV57201523, COSV57202875; called by muse, mutect2, varscan2
- LMF1 | c.513C>T p.F171= | Splice Region (SNP) | VAF 24/57 reads (42%) | catalogued as rs764311912, COSV51901728; called by muse, mutect2, varscan2
- LRP1B | c.10744G>A p.E3582K | Missense Mutation (SNP) | VAF 70/172 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as COSV67266617; called by muse, mutect2, varscan2
- LRP1B | c.6904C>T p.R2302W | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs199719207, COSV67266622; called by muse, mutect2, varscan2
- LRPPRC | c.3910G>A p.V1304M | Missense Mutation (SNP) | VAF 203/427 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs767065566, COSV53242587; called by muse, mutect2, varscan2
- LRRC31 | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52982477; called by muse, mutect2, varscan2
- LRRIQ3 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 44/47 reads (94%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs202037480, COSV63041614, COSV99063517; called by muse, varscan2
- LTBP3 | c.1585C>T p.P529S | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV57243683; called by muse, mutect2
- MAGEA3 | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 63/67 reads (94%) | SIFT tolerated (0.36); PolyPhen benign (0.026); catalogued as COSV64756479; called by muse, mutect2, varscan2
- MAP3K2 | c.1012T>G p.L338V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV61296008; called by muse, mutect2, varscan2
- MARCHF9 | c.902C>A p.A301D | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV56986430; called by muse, mutect2, varscan2
- MDN1 | c.10262C>T p.S3421L | Missense Mutation (SNP) | VAF 61/65 reads (94%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV65529112; called by muse, mutect2, varscan2
- MFN1 | c.1549C>T p.Q517* | Nonsense Mutation (SNP) | VAF 24/55 reads (44%) | catalogued as rs866295810, COSV54942063; called by muse, mutect2, varscan2
- MME | c.1276C>T p.L426F | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV64707567; called by muse, mutect2, varscan2
- MMP1 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT tolerated (0.06); PolyPhen benign (0.22); catalogued as COSV59511570; called by muse, mutect2, varscan2
- MMRN1 | c.2776G>A p.E926K | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.735); catalogued as rs762148913, COSV53333574; called by muse, mutect2, varscan2
- MOGAT2 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 71/131 reads (54%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV52221219; called by muse, mutect2, varscan2
- MORC1 | c.2500C>T p.P834S | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as rs377680519, COSV51715467; called by muse, mutect2, varscan2
- MUC16 | c.35587C>T p.P11863S | Missense Mutation (SNP) | VAF 82/136 reads (60%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.047); catalogued as COSV67488943; called by muse, mutect2, varscan2
- MUC16 | c.31222G>A p.G10408R | Missense Mutation (SNP) | VAF 73/249 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV67467760; called by muse, mutect2, varscan2
- MUC16 | c.18656A>G p.N6219S | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as COSV67488952, COSV67489365; called by muse, mutect2, varscan2
- MUC16 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs752724664, COSV67458170; called by muse, mutect2, varscan2
- MXRA5 | c.6992G>A p.G2331E | Missense Mutation (SNP) | VAF 95/103 reads (92%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV54226450; called by muse, mutect2, varscan2
- MXRA5 | c.4516A>T p.T1506S | Missense Mutation (SNP) | VAF 67/73 reads (92%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV54228491, COSV54247989; called by muse, mutect2, varscan2
- MYBPC2 | c.2291G>A p.G764E | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63099290; called by muse, mutect2, varscan2
- MYEF2 | c.1766G>A p.G589D | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV99982246; called by muse, mutect2, varscan2
- MYH1 | c.4775G>A p.R1592K | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.052); catalogued as rs1457247111, COSV56844482, COSV56848529; called by muse, mutect2, varscan2
- MYH13 | c.4118C>A p.A1373D | Missense Mutation (SNP) | VAF 51/204 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as rs62060459, COSV52840626; called by muse, mutect2, varscan2
- MYH15 | c.5519G>A p.G1840D | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV56318225; called by muse, mutect2, varscan2
- MYH7 | c.3138G>A p.M1046I | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs201195256, COSV62523106, COSV62525269; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH8 | c.5458G>A p.A1820T | Missense Mutation (SNP) | VAF 94/165 reads (57%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV67963110; called by muse, mutect2, varscan2
- MYLIP | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761995947, COSV62767510; called by muse, mutect2, varscan2
- MYO1G | c.506A>G p.N169S | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as rs1305178170, COSV51856737; called by muse, mutect2, varscan2
- MYO6 | c.980T>C p.I327T | Missense Mutation (SNP) | VAF 64/65 reads (98%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); catalogued as COSV64120987; called by muse, mutect2, varscan2
- MYOCD | c.2735C>T p.P912L | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58503434, COSV58510650, COSV58510874; called by muse, mutect2, varscan2
- NBEA | c.7537C>T p.R2513C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs868332409, COSV59800978; called by muse, mutect2, varscan2
- NCCRP1 | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 66/113 reads (58%) | catalogued as COSV59213058; called by muse, mutect2, varscan2
- NCKAP1L | c.1421-2A>G p.X474_splice | Splice Site (SNP) | VAF 7/38 reads (18%) | catalogued as COSV53211560; called by muse, mutect2, varscan2
- NDST4 | c.1931G>A p.G644E | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52110407; called by muse, mutect2, varscan2
- NETO1 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 51/53 reads (96%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs745312225, COSV55010235; called by muse, mutect2, varscan2
- NFAT5 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100591308; called by muse, mutect2, varscan2
- NFIL3 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 121/134 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1483988907, COSV52684536; called by muse, mutect2, varscan2
- NIPAL1 | c.811T>A p.Y271N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.392); catalogued as COSV55007587; called by muse, mutect2, varscan2
- NLRC3 | c.592T>G p.F198V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.27); catalogued as COSV57095165; called by muse, mutect2, varscan2
- NLRP11 | c.2861C>T p.P954L | Missense Mutation (SNP) | VAF 50/85 reads (59%) | SIFT tolerated (0.24); PolyPhen benign (0.306); catalogued as COSV64088613; called by muse, mutect2, varscan2
- NLRP9 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV60462242; called by muse, mutect2, varscan2
- NOL4 | c.598A>G p.K200E | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52359663; called by muse, mutect2, varscan2
- NPAP1 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.937); catalogued as COSV61508640; called by muse, mutect2, varscan2
- NPY1R | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.151); catalogued as COSV56715702; called by muse, mutect2, varscan2
- NPY5R | c.735A>T p.K245N | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.222); catalogued as COSV58453656; called by muse, mutect2, varscan2
- NSG2 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV100292681, COSV57459529; called by muse, mutect2, varscan2
- NTRK3 | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV62301385; called by muse, varscan2
- NUP54 | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV53575098, COSV53577241; called by muse, mutect2, varscan2
- NUP85 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.383); catalogued as COSV55466435; called by muse, mutect2, varscan2
- NUTM1 | c.1547G>A p.G516E | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as COSV59217548; called by muse, mutect2, varscan2
- OAS1 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV52538259; called by muse, mutect2, varscan2
- OBI1 | c.489del p.K163Nfs*12 | Frame Shift Del (DEL) | VAF 73/142 reads (51%) | catalogued as rs1439888587; called by mutect2, pindel, varscan2
- ODC1 | c.213T>G p.N71K | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52173354; called by muse, mutect2, varscan2
- OLFML1 | c.663C>A p.Y221* | Nonsense Mutation (SNP) | VAF 21/36 reads (58%) | catalogued as COSV55081633; called by muse, mutect2, varscan2
- OR10G7 | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as rs757153234, COSV57868701; called by muse, mutect2, varscan2
- OR11H1 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV99421539; called by mutect2, varscan2
- OR1S2 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 98/138 reads (71%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as rs756049313, COSV56920543; called by muse, mutect2, varscan2
- OR2A12 | c.46T>A p.F16I | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV68821935; called by muse, mutect2, varscan2
- OR2A14 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 74/265 reads (28%) | catalogued as COSV68718584, COSV68718702; called by muse, mutect2, varscan2
- OR2B6 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 68/240 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as rs200986280, COSV55128883; called by muse, mutect2, varscan2
- OR2J3 | c.609G>A p.M203I | Missense Mutation (SNP) | VAF 79/106 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs1458090557, COSV65849602; called by muse, mutect2, varscan2
- OR2L13 | c.850C>A p.L284I | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV63559702; called by muse, varscan2
- OR4A15 | c.680G>A p.S227N | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.461); catalogued as COSV59034606; called by muse, mutect2, varscan2
- OR4C13 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.066); catalogued as rs367655402; called by muse, mutect2, varscan2
- OR4E2 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 168/348 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57732237; called by muse, varscan2
- OR4N2 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as rs758817736, COSV60054949; called by muse, mutect2, varscan2
- OR4N5 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 66/135 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV61320373; called by muse, mutect2, varscan2
- OR4Q3 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 84/304 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV59177523; called by muse, varscan2
- OR51A2 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 101/109 reads (93%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV66748122; called by muse, mutect2, varscan2
- OR51G1 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as rs776718496, COSV58968867; called by muse, mutect2, varscan2
- OR51G2 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs867001321, COSV58992760; called by muse, mutect2, varscan2
- OR5AS1 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1298836482, COSV100546152, COSV57983051; called by muse, mutect2, varscan2
- OR5H14 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV71193516; called by muse, mutect2, varscan2
- OR6K3 | c.158T>A p.F53Y (on ENST00000368146; = p.F37Y on NM_001005327.2) | Missense Mutation (SNP) | VAF 65/167 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63746361; called by muse, mutect2, varscan2
- OR6Y1 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV56931180; called by muse, mutect2, varscan2
- OR8A1 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 49/61 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV52510190; called by muse, mutect2, varscan2
- OR8H3 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 115/371 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57908231; called by muse, mutect2, varscan2
- OR8J3 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs201535279; called by muse, mutect2, varscan2
- OR8K5 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.963); catalogued as COSV57887868, COSV57888064, COSV57888107; called by muse, mutect2, varscan2
- ORC4 | c.85T>A p.C29S | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV51576665; called by muse, mutect2, varscan2
- OSBP2 | c.980G>A p.G327D | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60248134; called by muse, mutect2, varscan2
- OTOP2 | c.1498C>T p.L500F | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1436687711, COSV58883493, COSV58883937; called by muse, mutect2, varscan2
- OTUD4 | c.1046C>T p.S349F (on ENST00000447906 / NM_001366057.1; = p.S284F on NM_001102653.1) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as COSV71382243; called by muse, mutect2, varscan2
- P2RY1 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.81); PolyPhen benign (0.013); catalogued as COSV100521699, COSV59310295; called by muse, mutect2, varscan2
- PALMD | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT tolerated (0.81); PolyPhen benign (0.315); catalogued as COSV54165731; called by muse, mutect2, varscan2
- PCDH15 | c.1991C>T p.S664L | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV57381049; called by muse, mutect2, varscan2
- PCDH17 | c.2578C>T p.P860S | Missense Mutation (SNP) | VAF 54/78 reads (69%) | SIFT tolerated (0.47); PolyPhen benign (0.014); catalogued as COSV64972341; called by muse, mutect2, varscan2
- PCDH18 | c.2482G>T p.V828F | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV61271648; called by muse, mutect2, varscan2
- PCDH19 | c.3110G>A p.R1037K (on ENST00000373034 / NM_001184880.2; = p.R989K on NM_020766.3) | Missense Mutation (SNP) | VAF 38/38 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV55270202; called by muse, varscan2
- PCDHA12 | c.2083G>A p.D695N | Missense Mutation (SNP) | VAF 37/41 reads (90%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.011); catalogued as rs267600400, COSV56510900; called by muse, mutect2, varscan2
- PCDHGA1 | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 115/127 reads (91%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV65296158; called by muse, mutect2, varscan2
- PCDHGA2 | c.1853C>T p.S618L | Missense Mutation (SNP) | VAF 63/72 reads (88%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.052); catalogued as rs776431934, COSV53946657; called by muse, mutect2, varscan2
- PCDHGB2 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs1246072554, COSV54018264; called by muse, mutect2, varscan2
- PCLO | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.164); catalogued as COSV61640018; called by muse, mutect2, varscan2
- PDE1A | c.1004A>C p.H335P | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59534439; called by muse, mutect2, varscan2
- PDE9A | c.1175T>C p.I392T | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145560514, COSV52330757; called by muse, mutect2, varscan2
- PDIA4 | c.1216G>A p.D406N (on ENST00000286091 / NM_001371244.1; = p.D405N on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.042); catalogued as rs150817731; called by muse, mutect2, varscan2
- PDLIM4 | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 31/34 reads (91%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV53805228; called by muse, mutect2, varscan2
- PDZD2 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56870665; called by muse, mutect2, varscan2
- PEAK1 | c.3232A>G p.T1078A | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs757255613, COSV56942108; called by muse, mutect2, varscan2
- PEG3 | c.4613C>T p.A1538V | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745497032, COSV99690655; called by muse, mutect2, varscan2
- PFKM | c.146A>G p.K49R | Missense Mutation (SNP) | VAF 99/141 reads (70%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.069); catalogued as COSV50304676, COSV50304677; called by muse, mutect2, varscan2
- PGAP1 | c.1916T>C p.V639A | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61329109; called by muse, mutect2, varscan2
- PHLPP1 | c.2336T>G p.L779W | Missense Mutation (SNP) | VAF 97/107 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53036917; called by muse, mutect2, varscan2
- PIK3CD | c.2546C>T p.A849V | Missense Mutation (SNP) | VAF 77/84 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63131406; called by muse, mutect2, varscan2
- PIK3R1 | c.1300G>A p.D434N (on ENST00000521381 / NM_181523.3; = p.D164N on NM_181504.4) | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV99160453; called by muse, varscan2
- PIK3R1 | c.1389T>G p.Y463* (on ENST00000521381 / NM_181523.3; = p.Y193* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 32/36 reads (89%) | catalogued as COSV57128433; called by muse, varscan2
- PKNOX2 | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 21/26 reads (81%) | catalogued as COSV53553194; called by muse, mutect2, varscan2
- PLCB1 | c.2081G>A p.G694E | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.47); catalogued as COSV62065403; called by muse, mutect2, varscan2
- PLCB4 | c.537A>T p.E179D | Missense Mutation (SNP) | VAF 75/152 reads (49%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.931); catalogued as COSV53815300; called by muse, mutect2, varscan2
- PLEKHG2 | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV52688914; called by muse, mutect2, varscan2
- PLEKHG2 | c.1447+1G>A p.X483_splice | Splice Site (SNP) | VAF 24/44 reads (55%) | catalogued as rs200814754, COSV52689199; called by muse, mutect2, varscan2
- PLEKHH3 | c.259A>G p.K87E | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV53191032; called by muse, mutect2, varscan2
- PLXNA4 | c.5161G>A p.D1721N | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV58155733; called by muse, mutect2, varscan2
- PLXNA4 | c.4898G>A p.S1633N | Missense Mutation (SNP) | VAF 101/388 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV58113571, COSV58155746; called by muse, mutect2, varscan2
- POLD1 | c.644C>G p.A215G | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV70956407, COSV70957021; called by muse, mutect2, varscan2
- POM121C | c.3311C>T p.T1104I (on ENST00000607367; = p.T862I on NM_001099415.3) | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV99993130; called by muse, mutect2
- PON3 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs1265571309, COSV55701203; called by muse, mutect2, varscan2
- POTEE | c.2392C>T p.P798S | Missense Mutation (SNP) | VAF 86/309 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV58224385; called by muse, varscan2
- PPM1N | c.1253A>G p.N418S | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV55595803; called by muse, mutect2, varscan2
- PPP1R13B | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 32/80 reads (40%) | catalogued as COSV52455726; called by muse, mutect2, varscan2
- PPP1R3A | c.871C>T p.H291Y | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs371083356; called by muse, mutect2, varscan2
- PPP4R3B | c.1577G>T p.G526V (on ENST00000616407 / NM_001122964.3; = p.G494V on NM_020463.4) | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV55408631; called by muse, mutect2, varscan2
- PPP4R4 | c.2237A>G p.N746S | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58557676; called by muse, mutect2, varscan2
- PRAMEF17 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 183/203 reads (90%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV101068809; called by muse, mutect2, varscan2
- PRDM10 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.733); catalogued as COSV58804606; called by muse, mutect2, varscan2
- PRDM9 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV57011905, COSV57012194; called by muse, mutect2, varscan2
- PROKR1 | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 77/157 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV58138822; called by muse, mutect2, varscan2
- PRSS1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 68/224 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV61191980; called by muse, mutect2, varscan2
- PSG4 | c.84G>A p.W28* | Nonsense Mutation (SNP) | VAF 86/133 reads (65%) | catalogued as COSV54939904; called by muse, mutect2, varscan2
- PTCH2 | c.1711C>T p.P571S | Missense Mutation (SNP) | VAF 37/44 reads (84%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as COSV64713204; called by muse, mutect2, varscan2
- PTGER2 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs762983405, COSV55420665; called by muse, varscan2
- PTPN4 | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV99751562; called by muse, mutect2, varscan2
- PTPRA | c.1382T>G p.M461R | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT tolerated (0.77); PolyPhen benign (0.024); catalogued as COSV53787673; called by muse, mutect2, varscan2
- PTPRC | c.1990T>C p.F664L | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV61419784; called by muse, mutect2, varscan2
- PUS7L | c.311G>A p.G104D | Missense Mutation (SNP) | VAF 24/616 reads (4%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV61262538; called by muse, mutect2
- RAI2 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 48/52 reads (92%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV58965998; called by muse, mutect2, varscan2
- RANBP17 | c.3005C>T p.S1002F | Missense Mutation (SNP) | VAF 156/359 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV66656041; called by muse, mutect2, varscan2
- RANBP2 | c.9410C>T p.S3137F | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1437128183, COSV51707553; called by muse, mutect2, varscan2
- RBL1 | c.598C>T p.H200Y | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1488518937, COSV60333172; called by muse, mutect2, varscan2
- RBM22 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 84/91 reads (92%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV52272958; called by muse, mutect2, varscan2
- REXO5 | c.1989G>C p.K663N | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV54474415; called by muse, mutect2, varscan2
- RIN3 | c.2581G>A p.E861K | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53654587; called by muse, mutect2, varscan2
- RNF17 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55049355; called by muse, mutect2, varscan2
- ROBO1 | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 115/219 reads (53%) | catalogued as COSV71397875; called by muse, mutect2, varscan2
- RTL8B | c.17A>G p.Q6R | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV66954477; called by muse, mutect2, varscan2
- RXFP1 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV57055740; called by muse, mutect2, varscan2
- RYR3 | c.8323G>A p.E2775K (on ENST00000389232; = p.E2776K on NM_001036.6) | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66806155; called by muse, mutect2, varscan2
- SCAP | c.2558C>T p.P853L | Missense Mutation (SNP) | VAF 38/41 reads (93%) | SIFT tolerated (0.23); PolyPhen benign (0.116); catalogued as rs771903635, COSV99651109; called by muse, mutect2, varscan2
- SCAP | c.2557C>T p.P853S | Missense Mutation (SNP) | VAF 39/42 reads (93%) | SIFT tolerated (0.56); PolyPhen benign (0.116); catalogued as COSV99651110; called by muse, mutect2, varscan2
- SCN5A | c.5338G>A p.E1780K (on ENST00000333535 / NM_198056.3; = p.E1779K on NM_000335.5) | Missense Mutation (SNP) | VAF 42/48 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV61120261; called by muse, mutect2, varscan2
- SCN7A | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 141/314 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.251); catalogued as rs1448558691, COSV69271113; called by muse, mutect2, varscan2
- SEMA3E | c.1285G>A p.G429R | Missense Mutation (SNP) | VAF 86/212 reads (41%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.947); catalogued as rs745855667, COSV57105807; called by muse, mutect2, varscan2
- SEMA6D | c.2158C>T p.L720F (on ENST00000316364 / NM_153618.2; = p.L658F on NM_020858.2) | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV60382930; called by muse, mutect2, varscan2
- SERPINA10 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV56228844; called by muse, mutect2, varscan2
- SERPINA3 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.164); catalogued as COSV67587021; called by muse, mutect2, varscan2
- SERPINA9 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); catalogued as rs777073491, COSV54075969; called by muse, mutect2, varscan2
- SETD1A | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 75/151 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.548); catalogued as rs146035438, COSV52685962; called by muse, mutect2, varscan2
- SEZ6L | c.458G>A p.G153D | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV50681596; called by muse, mutect2, varscan2
- SFSWAP | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV55520375, COSV55525270; called by muse, mutect2, varscan2
- SIGLEC7 | c.396G>A p.W132* | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as COSV58317603; called by muse, mutect2, varscan2
- SKIL | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV52062706; called by muse, mutect2, varscan2
- SLC10A5 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV72828468; called by muse, mutect2, varscan2
- SLC12A5 | c.995G>A p.G332E (on ENST00000454036 / NM_001134771.2; = p.G309E on NM_020708.5) | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as rs1371576683, COSV54787070; called by muse, mutect2, varscan2
- SLC13A3 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 96/213 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs866802774, COSV51717794; called by muse, mutect2, varscan2
- SLC14A1 | c.901T>C p.F301L | Missense Mutation (SNP) | VAF 53/96 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs1020183217, COSV58933856; called by muse, mutect2, varscan2
- SLC15A2 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as rs774984863, COSV55200455; called by muse, mutect2, varscan2
- SLC17A7 | c.582G>A p.W194* | Nonsense Mutation (SNP) | VAF 41/72 reads (57%) | catalogued as COSV55549866; called by muse, mutect2, varscan2
- SLC17A8 | c.1433A>C p.E478A | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as COSV60126301; called by muse, mutect2, varscan2
- SLC22A2 | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 57/61 reads (93%) | SIFT tolerated (0.69); PolyPhen benign (0.396); catalogued as rs756063752, COSV65266044, COSV65267697; called by muse, mutect2, varscan2
- SLC26A6 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs771585930, COSV50996203; called by muse, mutect2, varscan2
- SLC2A3 | c.1235C>T p.S412F | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV50007077; called by muse, mutect2, varscan2
- SLC30A1 | c.1130T>G p.L377R | Missense Mutation (SNP) | VAF 81/88 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65361542; called by muse, mutect2, varscan2
- SLC38A4 | c.919C>T p.H307Y | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs1470127177, COSV56970736; called by muse, mutect2, varscan2
- SLC39A6 | c.433C>T p.L145F | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1005978227, COSV52371100, COSV99309851; called by muse, mutect2, varscan2
- SLC44A3 | c.245C>T p.A82V (on ENST00000271227 / NM_001114106.3; = p.A34V on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/68 reads (93%) | SIFT tolerated (0.96); PolyPhen benign (0.081); catalogued as COSV54733419; called by muse, mutect2, varscan2
- SLC4A10 | c.115A>C p.K39Q | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV55796878; called by muse, mutect2, varscan2
- SLC5A7 | c.1598A>T p.K533I | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV50900990; called by muse, varscan2
- SLC5A7 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as rs200754655, COSV50901046, COSV50911778; called by muse, varscan2
- SLC5A8 | c.1370G>A p.G457E | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV73310564, COSV73311129; called by muse, mutect2, varscan2
- SLC7A10 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs865959657, COSV53506857; called by muse, mutect2, varscan2
- SLC7A2 | c.365C>T p.S122L (on ENST00000494857 / NM_001370338.1; = p.S162L on NM_003046.6) | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777770011, COSV50260346, COSV99135105; called by muse, mutect2, varscan2
- SLC9C1 | c.2481A>T p.L827F | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.454); catalogued as COSV59892336; called by muse, mutect2, varscan2
- SLCO1B3 | c.1634C>T p.S545F | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.291); catalogued as COSV53937134, COSV53944924; called by muse, mutect2, varscan2
- SLX1A | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV99246997; called by mutect2, varscan2
- SMC1B | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV61582195; called by muse, mutect2, varscan2
- SMR3A | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.294); catalogued as rs1241949701, COSV56949951, COSV56951246; called by muse, mutect2, varscan2
- SORCS3 | c.3026C>T p.P1009L | Missense Mutation (SNP) | VAF 28/32 reads (88%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV63798061; called by muse, mutect2, varscan2
- SORL1 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs1307010175, COSV52755640, COSV99494747; called by muse, mutect2, varscan2
- SORL1 | c.5233G>A p.G1745R | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as COSV52753820; called by muse, mutect2, varscan2
- SORL1 | c.5234G>T p.G1745V | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV52752209, COSV99495688; called by muse, mutect2, varscan2
- SP6 | c.870C>A p.F290L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV60618974; called by muse, mutect2, varscan2
- SRRM4 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs1318238618, COSV57416862; called by muse, mutect2, varscan2
- SSTR2 | c.860C>T p.T287I | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.756); catalogued as COSV59535938; called by muse, varscan2
- SSTR2 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.129); catalogued as COSV59535959; called by muse, varscan2
- STAG3 | c.2368G>A p.D790N | Missense Mutation (SNP) | VAF 114/119 reads (96%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.482); catalogued as COSV57934223; called by muse, mutect2, varscan2
- STAT2 | c.1349C>T p.T450I | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV58477114; called by muse, mutect2, varscan2
- STAU1 | c.775G>A p.E259K (on ENST00000371856 / NM_001319135.1; = p.E178K on NM_004602.3) | Missense Mutation (SNP) | VAF 179/418 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.65); catalogued as COSV61462235; called by muse, mutect2, varscan2
- STEAP3 | c.49A>C p.S17R | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV61530791; called by muse, mutect2, varscan2
- STK33 | c.1295G>A p.G432E | Missense Mutation (SNP) | VAF 77/253 reads (30%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as rs377485276; called by muse, mutect2, varscan2
- STYXL2 | c.3248G>A p.G1083E | Missense Mutation (SNP) | VAF 38/42 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV54809416; called by muse, mutect2, varscan2
- SVEP1 | c.9713C>T p.P3238L | Missense Mutation (SNP) | VAF 34/39 reads (87%) | SIFT tolerated (0.07); PolyPhen benign (0.411); catalogued as COSV52843234; called by muse, mutect2, varscan2
- SVEP1 | c.4697C>T p.P1566L | Missense Mutation (SNP) | VAF 39/43 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65689359; called by muse, mutect2, varscan2
- SYN2 | c.1187G>A p.G396E | Missense Mutation (SNP) | VAF 185/416 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70286372; called by muse, mutect2, varscan2
- SYT1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs138582600, COSV54034805; called by muse, mutect2, varscan2
- SYT10 | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.17); catalogued as rs866101269, COSV57337286; called by muse, mutect2, varscan2
- SYT5 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 67/93 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs868459585, COSV62831211; called by muse, mutect2, varscan2
- SYT9 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 48/76 reads (63%) | SIFT tolerated (0.29); PolyPhen benign (0.045); catalogued as COSV59624080; called by muse, mutect2, varscan2
- TACR2 | c.522G>A p.M174I | Missense Mutation (SNP) | VAF 63/73 reads (86%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as COSV64822697; called by muse, mutect2, varscan2
- TBK1 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.249); catalogued as COSV59158054; called by muse, mutect2, varscan2
- TBL1X | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 47/54 reads (87%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV54287436; called by muse, mutect2, varscan2
- TC2N | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV61748038; called by muse, mutect2, varscan2
- TCTEX1D2 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV100308970; called by muse, mutect2
- TEAD4 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV63282319; called by muse, mutect2, varscan2
- TENM1 | c.1427C>T p.S476F | Missense Mutation (SNP) | VAF 45/47 reads (96%) | SIFT tolerated (0.1); PolyPhen benign (0.208); catalogued as COSV64441151; called by muse, mutect2, varscan2
- TENM3 | c.185G>A p.R62K | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.135); catalogued as COSV69308423; called by muse, mutect2, varscan2
- TEX55 | c.1409C>T p.S470L | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as COSV55212684; called by muse, mutect2, varscan2
- THSD1 | c.2176C>T p.P726S | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1444095268, COSV51627309; called by muse, mutect2, varscan2
- TKTL2 | c.1037C>T p.T346M | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.793); catalogued as COSV54920958; called by muse, mutect2, varscan2
- TLE2 | c.1828G>A p.D610N | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53582846; called by muse, mutect2, varscan2
- TMEM109 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.301); catalogued as COSV50019804; called by muse, mutect2, varscan2
- TMEM132A | c.3066C>A p.S1022R (on ENST00000453848 / NM_178031.3; = p.S1023R on NM_017870.4) | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50004048, COSV50019872; called by muse, mutect2
- TMEM59L | c.571A>T p.I191L | Missense Mutation (SNP) | VAF 95/146 reads (65%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV53243290, COSV53243428; called by muse, mutect2, varscan2
- TREML2 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs762890750, COSV72438998; called by muse, mutect2
- TRHR | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61236156; called by muse, mutect2, varscan2
- TRIP6 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs546644102, COSV52342651; called by muse, mutect2, varscan2
- TRMT5 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143033104; called by muse, mutect2, varscan2
- TRPA1 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 51/79 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs755681762, COSV51572411; called by muse, mutect2, varscan2
- TRPC4 | c.1015C>T p.L339F | Missense Mutation (SNP) | VAF 48/65 reads (74%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV58995967, COSV59015048; called by muse, mutect2, varscan2
- TRRAP | c.2293C>T p.R765C | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1475672755, COSV62852932; called by muse, mutect2, varscan2
- TSHZ2 | c.2312A>T p.K771I | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61591070; called by muse, mutect2, varscan2
- TTN | c.93449G>A p.R31150K (on ENST00000591111; = p.R23726K on NM_003319.4) | Missense Mutation (SNP) | VAF 61/135 reads (45%) | PolyPhen benign (0); catalogued as COSV60299015; called by muse, mutect2, varscan2
- TTN | c.89422G>A p.E29808K (on ENST00000591111; = p.E22384K on NM_003319.4) | Missense Mutation (SNP) | VAF 192/400 reads (48%) | PolyPhen probably damaging (0.994); catalogued as rs374474093, COSV60299057; called by muse, mutect2, varscan2
- TTN | c.60055C>T p.P20019S (on ENST00000591111; = p.P12595S on NM_003319.4) | Missense Mutation (SNP) | VAF 47/94 reads (50%) | PolyPhen probably damaging (0.998); catalogued as COSV60299145; called by muse, mutect2, varscan2
- TTN | c.19403C>T p.S6468L (on ENST00000591111; = p.S5541L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/63 reads (41%) | PolyPhen benign (0.001); catalogued as rs201586695, COSV60195448; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TUT7 | c.3878C>T p.S1293L | Missense Mutation (SNP) | VAF 33/36 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV52898433; called by muse, mutect2, varscan2
- UBN1 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV99278730; called by muse, mutect2, varscan2
- UBQLNL | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV66494390; called by muse, mutect2, varscan2
- UGT2B15 | c.1304A>T p.N435I | Missense Mutation (SNP) | VAF 96/167 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV57736278; called by muse, mutect2, varscan2
- UGT2B15 | c.417G>A p.M139I | Missense Mutation (SNP) | VAF 67/223 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV57736293; called by muse, mutect2, varscan2
- UNC13C | c.1505C>T p.S502L | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as COSV52916719, COSV99518229; called by muse, mutect2, varscan2
- UNC5CL | c.673C>T p.L225F | Missense Mutation (SNP) | VAF 58/95 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.391); catalogued as rs1245526554, COSV55111763; called by muse, mutect2, varscan2
- UNC80 | c.181C>T p.L61F | Missense Mutation (SNP) | VAF 67/176 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV55890697, COSV55903909; called by muse, mutect2, varscan2
- USP22 | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54948488, COSV54948652; called by muse, mutect2, varscan2
- WDR35 | c.3001A>G p.T1001A (on ENST00000345530 / NM_001006657.2; = p.T990A on NM_020779.4) | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1184414721, COSV55606399; called by muse, mutect2, varscan2
- WDR43 | c.1702C>T p.L568F | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68019423; called by muse, mutect2
- XIRP2 | c.3638G>A p.R1213K (on ENST00000628543; = p.R1388K on NM_152381.6) | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.978); catalogued as COSV54729764; called by muse, mutect2, varscan2
- YPEL3 | c.271G>A p.E91K (on ENST00000398838 / NM_001145524.2; = p.E129K on NM_031477.5) | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV54223097; called by muse, mutect2, varscan2
- YTHDF2 | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 32/35 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV65724050; called by muse, mutect2, varscan2
- ZBTB7B | c.483G>C p.Q161H (on ENST00000292176; = p.Q195H on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV52694599; called by muse, mutect2, varscan2
- ZDHHC17 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as COSV58353645; called by muse, mutect2, varscan2
- ZFP2 | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV63725894; called by muse, mutect2, varscan2
- ZFPM2 | c.2957G>A p.G986E | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.382); catalogued as COSV65875528; called by muse, mutect2, varscan2
- ZIC3 | c.611G>A p.S204N | Missense Mutation (SNP) | VAF 44/47 reads (94%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV54976500; called by muse, mutect2, varscan2
- ZNF212 | c.953G>A p.C318Y | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60026022; called by muse, mutect2, varscan2
- ZNF3 | c.635C>T p.T212I | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.211); catalogued as rs771508637, COSV52795338; called by muse, mutect2, varscan2
- ZNF318 | c.4439C>T p.P1480L | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV58936827; called by muse, mutect2, varscan2
- ZNF354B | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59367209; called by muse, mutect2, varscan2
- ZNF484 | c.2542C>T p.Q848* | Nonsense Mutation (SNP) | VAF 66/74 reads (89%) | catalogued as rs755525980, COSV60259383; called by muse, mutect2, varscan2
- ZNF491 | c.760C>A p.R254S | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV60057334, COSV60058722; called by muse, mutect2, varscan2
- ZNF560 | c.2287A>T p.M763L | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0.092); catalogued as COSV56871090; called by muse, mutect2, varscan2
- ZNF569 | c.1694T>C p.L565P | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57595186; called by muse, mutect2, varscan2
- ZNF607 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1209290645, COSV62206253; called by muse, mutect2, varscan2
- ZNF707 | c.907C>T p.L303F | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62311713; called by muse, mutect2, varscan2
- ZNF768 | c.1108G>T p.E370* | Nonsense Mutation (SNP) | VAF 23/63 reads (37%) | catalogued as COSV63323968; called by muse, mutect2, varscan2
- ZNF793 | c.57A>C p.Q19H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV71325164; called by muse, mutect2
- ZNF808 | c.2411C>T p.S804L | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.782); catalogued as COSV63121368; called by muse, mutect2, varscan2
- ZPLD1 | c.824C>T p.S275F (on ENST00000466937 / NM_001329788.1; = p.S291F on NM_175056.2) | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs758168750, COSV100083527, COSV60355767; called by muse, mutect2, varscan2
- CEP170 | c.4343G>A p.R1448Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- IGHV4-31 | c.329A>G p.D110G | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.529); called by muse, mutect2
- IGKV1-9 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 86/211 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRAMEF15 | c.1115T>A p.I372N | Missense Mutation (SNP) | VAF 161/214 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- THOP1 | c.983_987dup p.G330Sfs*14 | Frame Shift Ins (INS) | VAF 11/39 reads (28%) | called by mutect2, pindel, varscan2
- TRAV1-2 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF385A | c.756del p.E253Rfs*24 (on ENST00000338010 / NM_001130967.3; = p.E233Rfs*24 on NM_015481.3) | Frame Shift Del (DEL) | VAF 49/215 reads (23%) | called by mutect2, pindel, varscan2
- ZNF628 | c.462del p.K155Rfs*272 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | called by mutect2, varscan2
- ACLY | c.708C>T p.I236= | Silent (SNP) | VAF 43/161 reads (27%) | catalogued as rs374252025; called by muse, mutect2, varscan2
- ACTL9 | c.447C>T p.S149= | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as rs782706282, COSV61007041; called by muse, mutect2, varscan2
- ACVRL1 | c.1317G>A p.K439= | Silent (SNP) | VAF 737/793 reads (93%) | catalogued as COSV66360884; called by muse, mutect2, varscan2
- ADAM18 | c.732C>T p.S244= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV55853965; called by muse, mutect2, varscan2
- ADAMTS18 | c.136T>C p.L46= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV51400863; called by muse, mutect2, varscan2
- ADAMTS7 | c.1200A>C p.G400= | Silent (SNP) | VAF 80/169 reads (47%) | catalogued as COSV66309195; called by muse, mutect2, varscan2
- ADD1 | c.777C>T p.S259= | Silent (SNP) | VAF 44/128 reads (34%) | catalogued as rs1318077462, COSV53273546; called by muse, varscan2
- ADGRF5 | c.9C>T p.S3= | Silent (SNP) | VAF 43/132 reads (33%) | catalogued as COSV51939170; called by muse, mutect2, varscan2
- ADH1B | c.1098G>A p.G366= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV59298214; called by muse, mutect2, varscan2
- AIFM3 | c.429G>A p.E143= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV59003442; called by muse, mutect2, varscan2
- ANK1 | c.5388G>A p.V1796= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as COSV55893484; called by muse, mutect2, varscan2
- AOC1 | c.1845C>T p.I615= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as COSV62868164; called by muse, mutect2, varscan2
- APOB | c.4425G>A p.K1475= | Silent (SNP) | VAF 309/740 reads (42%) | catalogued as COSV99268456; called by mutect2, varscan2
- ARAP2 | c.3483A>G p.E1161= | Silent (SNP) | VAF 30/51 reads (59%) | catalogued as COSV58291380; called by muse, mutect2, varscan2
- ARHGAP5 | c.2445C>T p.S815= | Silent (SNP) | VAF 51/110 reads (46%) | catalogued as rs756332483, COSV61536419; called by muse, mutect2, varscan2
- ARHGEF5 | c.2565C>T p.P855= | Silent (SNP) | VAF 45/137 reads (33%) | catalogued as rs1408519736, COSV50217753; called by muse, mutect2
- ART1 | c.276G>A p.R92= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as rs1482109018, COSV51706771; called by muse, mutect2, varscan2
- ATP13A5 | c.1206C>T p.I402= | Silent (SNP) | VAF 42/75 reads (56%) | catalogued as COSV60867411, COSV60875675; called by muse, mutect2, varscan2
- B3GNT3 | c.126G>A p.A42= | Silent (SNP) | VAF 25/34 reads (74%) | catalogued as rs767072314, COSV59437768; called by muse, varscan2
- B4GALNT2 | c.1518G>A p.G506= | Silent (SNP) | VAF 82/158 reads (52%) | catalogued as COSV55927982; called by muse, mutect2, varscan2
- B4GALNT4 | c.1050C>T p.Y350= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs1191534226, COSV100327902; called by muse, mutect2, varscan2
- BCL9L | c.3063C>T p.S1021= | Silent (SNP) | VAF 39/47 reads (83%) | catalogued as COSV52683546; called by muse, mutect2, varscan2
- BIN2 | c.1473C>T p.N491= | Silent (SNP) | VAF 362/400 reads (91%) | catalogued as COSV57207616; called by muse, mutect2, varscan2
- BPIFA2 | c.447C>T p.S149= | Silent (SNP) | VAF 117/227 reads (52%) | catalogued as COSV53612528; called by muse, mutect2, varscan2
- C10orf120 | c.681G>A p.K227= | Silent (SNP) | VAF 25/27 reads (93%) | catalogued as COSV61492572; called by muse, mutect2, varscan2
- CA2 | c.393G>A p.G131= | Silent (SNP) | VAF 51/213 reads (24%) | catalogued as COSV53406225; called by muse, mutect2, varscan2
- CACNA1C | c.1185C>T p.F395= | Silent (SNP) | VAF 68/169 reads (40%) | catalogued as rs1455190942, COSV59713206; called by muse, mutect2, varscan2
- CACNA2D4 | c.2439C>T p.F813= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs1238015257, COSV54958514; called by muse, mutect2, varscan2
- CACNG4 | c.387G>A p.R129= | Silent (SNP) | VAF 66/143 reads (46%) | catalogued as COSV50924246; called by muse, mutect2, varscan2
- CARD6 | c.987C>T p.F329= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV54568678; called by muse, mutect2, varscan2
- CARMIL2 | c.3822C>T p.S1274= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV54670038; called by muse, mutect2, varscan2
- CDH4 | c.1299C>T p.I433= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as COSV64671664; called by muse, mutect2, varscan2
- CDH5 | c.1683G>A p.G561= | Silent (SNP) | VAF 71/138 reads (51%) | catalogued as COSV58519618; called by muse, mutect2, varscan2
- CDH8 | c.1866C>T p.G622= | Silent (SNP) | VAF 39/69 reads (57%) | catalogued as COSV54857645; called by muse, mutect2, varscan2
- CDH9 | c.981G>A p.G327= | Silent (SNP) | VAF 113/205 reads (55%) | catalogued as COSV50412225, COSV50441075; called by muse, mutect2, varscan2
- CDKL2 | c.708T>G p.A236= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV56735203; called by muse, mutect2, varscan2
- CFAP70 | c.1201C>T p.L401= | Silent (SNP) | VAF 87/99 reads (88%) | catalogued as rs368424286, COSV60286420; called by muse, varscan2
- CHL1 | c.3615C>T p.P1205= (on ENST00000397491 / NM_001253387.1; = p.P1221= on NM_006614.4) | Silent (SNP) | VAF 28/47 reads (60%) | catalogued as COSV56595441, COSV99852545; called by muse, mutect2, varscan2
- CHRNB4 | c.486C>T p.F162= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as rs80249872, COSV55717187; called by muse, mutect2, varscan2
- CIB3 | c.159G>A p.K53= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as COSV54167408, COSV99521764; called by muse, mutect2, varscan2
- CLDN11 | c.525C>T p.I175= | Silent (SNP) | VAF 96/210 reads (46%) | catalogued as COSV50356037; called by muse, mutect2, varscan2
- CLDN18 | c.33C>T p.F11= | Silent (SNP) | VAF 56/117 reads (48%) | catalogued as COSV59301692; called by muse, mutect2, varscan2
- COL6A6 | c.4650G>A p.K1550= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as COSV62035537; called by muse, mutect2, varscan2
- CRX | c.612C>T p.S204= | Silent (SNP) | VAF 72/110 reads (65%) | catalogued as rs750145677, COSV55757772; called by muse, mutect2, varscan2
- CSMD3 | c.9612G>A p.T3204= (on ENST00000297405 / NM_001363185.1; = p.T3035= on NM_052900.3) | Silent (SNP) | VAF 34/120 reads (28%) | catalogued as rs183191388; called by muse, mutect2, varscan2
- CSMD3 | c.8607C>T p.S2869= (on ENST00000297405 / NM_001363185.1; = p.S2700= on NM_052900.3) | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV52159949; called by muse, mutect2, varscan2
- DCC | c.4077G>A p.P1359= | Silent (SNP) | VAF 92/104 reads (88%) | catalogued as rs571287631, COSV71432561; called by muse, mutect2, varscan2
- DDN | c.231C>T p.S77= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs776655597, COSV60294478; called by muse, mutect2, varscan2
- DDX60L | c.924C>T p.P308= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as COSV52720686; called by muse, mutect2, varscan2
- DNAH1 | c.7332C>T p.S2444= | Silent (SNP) | VAF 91/100 reads (91%) | catalogued as COSV70235119; called by muse, mutect2, varscan2
- DNAH11 | c.7998C>T p.F2666= | Silent (SNP) | VAF 65/194 reads (34%) | catalogued as rs764608320, COSV60977237; called by muse, mutect2, varscan2
- DNAH11 | c.11199G>A p.L3733= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV60977270; called by muse, mutect2, varscan2
- DNMT1 | c.3831C>T p.S1277= | Silent (SNP) | VAF 25/37 reads (68%) | catalogued as COSV61582991; called by muse, mutect2, varscan2
- DSCAML1 | c.573G>A p.V191= (on ENST00000321322; = p.V131= on NM_020693.4) | Silent (SNP) | VAF 24/27 reads (89%) | catalogued as rs757799783, COSV58401263; called by muse, mutect2, varscan2
- DSTYK | c.804C>T p.I268= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as COSV65688245; called by muse, mutect2
- DYNC1LI2 | c.780G>A p.R260= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as rs777813042, COSV99263295; called by muse, mutect2, varscan2
- DYSF | c.5067G>A p.P1689= | Silent (SNP) | VAF 77/190 reads (41%) | catalogued as rs750640522, COSV50454937, COSV99247944; ClinVar: likely benign; called by muse, mutect2, varscan2
- DYSF | c.5619C>T p.F1873= | Silent (SNP) | VAF 45/130 reads (35%) | catalogued as COSV50548385; called by muse, mutect2, varscan2
- EMC10 | c.573C>T p.T191= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as rs773373720, COSV58543154; called by muse, mutect2, varscan2
- ERICH6 | c.573G>A p.E191= | Silent (SNP) | VAF 40/83 reads (48%) | catalogued as COSV55802857; called by muse, mutect2, varscan2
- EVI5L | c.369C>T p.I123= | Silent (SNP) | VAF 28/37 reads (76%) | catalogued as COSV54488331; called by muse, mutect2, varscan2
- EVI5L | c.1368C>T p.F456= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as rs371069285; called by muse, mutect2, varscan2
- EXPH5 | c.4755G>A p.G1585= | Silent (SNP) | VAF 25/39 reads (64%) | catalogued as rs144642316, COSV56206689; called by muse, mutect2, varscan2
- FAM135B | c.1944G>A p.L648= | Silent (SNP) | VAF 64/103 reads (62%) | catalogued as rs752047390, COSV52749447; called by muse, mutect2, varscan2
- FAM20A | c.975G>A p.T325= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as rs150508189, COSV56836451; called by muse, mutect2, varscan2
- FAM71D | c.582G>A p.T194= | Silent (SNP) | VAF 57/119 reads (48%) | catalogued as COSV61294992; called by muse, mutect2, varscan2
- FAM91A1 | c.591C>T p.I197= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as rs757403971, COSV58237853; called by muse, mutect2, varscan2
- FAT3 | c.2118G>A p.L706= | Silent (SNP) | VAF 299/502 reads (60%) | catalogued as rs781607497, COSV53113918; called by muse, mutect2, varscan2
- FER1L6 | c.444C>A p.I148= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as COSV67552463; called by muse, mutect2, varscan2
- FGFR2 | c.1746C>T p.P582= | Silent (SNP) | VAF 125/137 reads (91%) | catalogued as rs369850306; called by muse, mutect2, varscan2
- FGFR4 | c.1815C>T p.S605= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs933337333, COSV52809126; called by muse, mutect2
- FLNC | c.4314G>A p.K1438= | Silent (SNP) | VAF 59/210 reads (28%) | catalogued as COSV57963500; called by muse, mutect2, varscan2
- FLT3 | c.1581C>T p.I527= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as COSV54054836; called by muse, mutect2, varscan2
- FNDC3B | c.2190C>T p.V730= | Silent (SNP) | VAF 85/192 reads (44%) | catalogued as rs200807692, COSV61048489; called by muse, mutect2, varscan2
- FOSL2 | c.843C>T p.V281= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV53105516; called by muse, mutect2, varscan2
- FOXG1 | c.1350C>T p.T450= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV57399093; called by muse, mutect2, varscan2
- FOXP2 | c.888C>T p.S296= | Silent (SNP) | VAF 34/123 reads (28%) | catalogued as COSV63492943; called by muse, mutect2, varscan2
- FSIP1 | c.342A>G p.Q114= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV63226606; called by muse, mutect2, varscan2
- FZR1 | c.39C>T p.I13= | Silent (SNP) | VAF 75/136 reads (55%) | catalogued as rs914230986, COSV58053391; called by muse, mutect2, varscan2
- GALNT13 | c.501G>A p.E167= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as rs761139906, COSV67208643; called by muse, mutect2, varscan2
- GALNT14 | c.1473C>T p.V491= | Silent (SNP) | VAF 61/134 reads (46%) | catalogued as COSV61110276; called by muse, mutect2, varscan2
- GARRE1 | c.2289G>A p.Q763= | Silent (SNP) | VAF 123/186 reads (66%) | catalogued as COSV55103310; called by muse, mutect2, varscan2
- GC | c.1062T>C p.T354= | Silent (SNP) | VAF 34/54 reads (63%) | catalogued as COSV56739579; called by muse, mutect2, varscan2
- GCLC | c.220C>T p.L74= (on ENST00000643939; = p.L78= on NM_001498.4) | Silent (SNP) | VAF 48/159 reads (30%) | catalogued as COSV57597539; called by muse, mutect2, varscan2
- GFAP | c.996G>A p.E332= | Silent (SNP) | VAF 36/56 reads (64%) | catalogued as COSV53653241; called by muse, mutect2, varscan2
- GJD2 | c.561C>T p.S187= | Silent (SNP) | VAF 83/175 reads (47%) | catalogued as COSV51749977; called by muse, mutect2
- GLI2 | c.813T>C p.G271= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV58050204; called by muse, mutect2, varscan2
- GLI3 | c.4647G>A p.A1549= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV67894192; called by muse, mutect2, varscan2
- GLP1R | c.1272C>T p.H424= | Silent (SNP) | VAF 83/308 reads (27%) | catalogued as rs983452956, COSV64716282; called by muse, mutect2, varscan2
- GRAMD1B | c.1782G>A p.R594= | Silent (SNP) | VAF 14/14 reads (100%) | catalogued as COSV59209869; called by muse, mutect2, varscan2
- H4C4 | c.187C>T p.L63= | Silent (SNP) | VAF 67/122 reads (55%) | catalogued as rs755124179, COSV100534512, COSV61590657; called by muse, mutect2, varscan2
- H4C4 | c.186C>T p.F62= | Silent (SNP) | VAF 65/120 reads (54%) | catalogued as rs761302691, COSV61592152; called by muse, mutect2, varscan2
- HYDIN | c.4425C>T p.I1475= | Silent (SNP) | VAF 85/189 reads (45%) | catalogued as rs752475652, COSV66832247; called by muse, mutect2, varscan2
- IGHV1-18 | c.174G>A p.Q58= | Silent (SNP) | VAF 105/264 reads (40%) | called by muse, mutect2, varscan2
- IGHV4-39 | c.31C>T p.L11= | Silent (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- IGKV1-9 | c.303G>A p.Q101= | Silent (SNP) | VAF 87/224 reads (39%) | catalogued as rs1558615994; called by muse, mutect2, varscan2
- ILDR1 | c.801C>T p.L267= (on ENST00000344209 / NM_001199799.2; = p.L223= on NM_175924.4) | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as COSV56553296; called by muse, varscan2
- ISM1 | c.1224C>G p.T408= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as rs763632064, COSV52607614; called by muse, mutect2
- ITGA5 | c.1200G>A p.G400= | Silent (SNP) | VAF 23/120 reads (19%) | catalogued as COSV53220294; called by muse, mutect2, varscan2
- JAKMIP1 | c.972G>A p.E324= | Silent (SNP) | VAF 70/97 reads (72%) | catalogued as COSV51543579; called by muse, mutect2, varscan2
- JAKMIP3 | c.859T>C p.L287= | Silent (SNP) | VAF 27/28 reads (96%) | catalogued as COSV53828632; called by muse, mutect2, varscan2
- KALRN | c.2763C>T p.S921= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as COSV53778001; called by muse, mutect2, varscan2
- KCNH5 | c.2334C>T p.N778= | Silent (SNP) | VAF 41/99 reads (41%) | catalogued as COSV59774725; called by muse, mutect2, varscan2
- KCNH6 | c.285C>T p.D95= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as rs1180178562, COSV59007081; called by muse, mutect2, varscan2
- KIAA0319 | c.2073C>T p.F691= | Silent (SNP) | VAF 35/150 reads (23%) | catalogued as COSV65501751; called by muse, mutect2, varscan2
- KIAA0895 | c.1092C>T p.P364= (on ENST00000297063 / NM_001100425.2; = p.P313= on NM_015314.3) | Silent (SNP) | VAF 21/102 reads (21%) | catalogued as COSV51713600; called by muse, mutect2, varscan2
- KIAA1328 | c.1323G>A p.R441= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV54463751; called by muse, mutect2, varscan2
- KIF4B | c.3585G>A p.S1195= | Silent (SNP) | VAF 17/18 reads (94%) | catalogued as COSV70529673; called by muse, mutect2, varscan2
- KMT2D | c.16404C>T p.G5468= | Silent (SNP) | VAF 15/20 reads (75%) | catalogued as rs1264342770, COSV99986323; called by muse, mutect2, varscan2
- LAMA3 | c.4170C>T p.D1390= | Silent (SNP) | VAF 91/143 reads (64%) | catalogued as COSV58078279; called by muse, mutect2, varscan2
- LIG1 | c.409C>T p.L137= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV54395518; called by muse, mutect2
- LNX2 | c.1120T>C p.L374= | Silent (SNP) | VAF 39/237 reads (16%) | catalogued as COSV60337964; called by muse, mutect2, varscan2
- LPO | c.2037C>T p.V679= | Silent (SNP) | VAF 50/121 reads (41%) | catalogued as COSV51861970; called by muse, mutect2, varscan2
- MAB21L2 | c.1008G>A p.E336= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV58262432, COSV58263336; called by muse, mutect2, varscan2
- MAGEA3 | c.750C>T p.F250= | Silent (SNP) | VAF 95/103 reads (92%) | catalogued as rs782271747, COSV64756293; called by muse, mutect2, varscan2
- MOGAT3 | c.270G>A p.R90= | Silent (SNP) | VAF 112/318 reads (35%) | catalogued as COSV56176729; called by muse, mutect2, varscan2
- MTMR4 | c.1167T>G p.A389= | Silent (SNP) | VAF 40/81 reads (49%) | catalogued as COSV60203179; called by muse, mutect2, varscan2
- MTUS1 | c.2478G>A p.E826= | Silent (SNP) | VAF 44/135 reads (33%) | catalogued as COSV50581398; called by muse, mutect2, varscan2
- MUC3A | c.8937C>T p.R2979= | Silent (SNP) | VAF 26/176 reads (15%) | catalogued as COSV60223751; called by muse, mutect2
- MYH13 | c.75C>T p.I25= | Silent (SNP) | VAF 20/29 reads (69%) | catalogued as rs776603506, COSV52821522; called by muse, mutect2, varscan2
- MYOM2 | c.2922G>A p.K974= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV50762088; called by muse, mutect2, varscan2
- NALCN | c.3834C>T p.L1278= | Silent (SNP) | VAF 64/94 reads (68%) | catalogued as rs757660166, COSV51961048; called by muse, mutect2, varscan2
- NAV2 | c.2259C>T p.I753= (on ENST00000396087 / NM_001244963.2; = p.I730= on NM_145117.5) | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs773721352, COSV62333092; called by muse, mutect2, varscan2
- NCAM1 | c.1335G>A p.T445= (on ENST00000316851 / NM_181351.5; = p.T435= on NM_000615.7) | Silent (SNP) | VAF 22/26 reads (85%) | catalogued as rs375199115, COSV57516152; called by muse, mutect2, varscan2
- NEB | c.7812G>A p.V2604= | Silent (SNP) | VAF 230/553 reads (42%) | catalogued as COSV51454537; called by muse, varscan2
- NEUROD6 | c.291G>A p.Q97= | Silent (SNP) | VAF 65/451 reads (14%) | catalogued as COSV51770368; called by muse, mutect2, varscan2
- NFAT5 | c.543C>T p.S181= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as COSV100591309; called by muse, mutect2, varscan2
- NLRP2 | c.2643G>A p.G881= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV54759531; called by muse, mutect2, varscan2
- NLRP5 | c.1263C>T p.V421= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs763332031, COSV66763079, COSV66763950; called by mutect2, varscan2
- NOL4 | c.1320C>T p.I440= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV52343429; called by muse, mutect2, varscan2
- NPAP1 | c.282C>T p.I94= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as rs1450298083, COSV61510605; called by muse, mutect2, varscan2
- NTRK3 | c.1884C>T p.F628= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as COSV62295852; called by muse, varscan2
- OR2L13 | c.927C>T p.F309= | Silent (SNP) | VAF 26/29 reads (90%) | catalogued as rs867211202, COSV63548408; called by muse, varscan2
- OR4A5 | c.759C>T p.F253= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV60521402, COSV60521592; called by muse, mutect2, varscan2
- OR4K17 | c.660G>A p.L220= | Silent (SNP) | VAF 63/132 reads (48%) | catalogued as rs1215043581, COSV59648995; called by muse, mutect2, varscan2
- OR4K5 | c.897G>A p.R299= | Silent (SNP) | VAF 81/231 reads (35%) | catalogued as rs749816085, COSV60003526; called by muse, mutect2, varscan2
- OR51B2 | c.483T>A p.L161= | Silent (SNP) | VAF 34/51 reads (67%) | catalogued as COSV60917575; called by muse, mutect2, varscan2
- OR51I1 | c.666G>A p.L222= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV104430772, COSV66508512; called by muse, mutect2, varscan2
- OR52A1 | c.858C>T p.V286= | Silent (SNP) | VAF 70/118 reads (59%) | catalogued as COSV61092746; called by muse, mutect2, varscan2
- OR5B3 | c.453C>T p.F151= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs184127928, COSV58678514; called by muse, mutect2, varscan2
- OR5K3 | c.159A>G p.Q53= | Silent (SNP) | VAF 109/238 reads (46%) | catalogued as COSV67350607; called by muse, mutect2, varscan2
- OR5M11 | c.612C>T p.F204= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV73141989; called by muse, mutect2, varscan2
- OR6K6 | c.198C>T p.I66= (on ENST00000368144; = p.I42= on NM_001005184.1) | Silent (SNP) | VAF 159/166 reads (96%) | catalogued as COSV63744789; called by muse, mutect2, varscan2
- PCDHA13 | c.204C>T p.S68= | Silent (SNP) | VAF 112/128 reads (88%) | catalogued as rs1554174267, COSV56539701; called by muse, mutect2, varscan2
- PDE1C | c.774C>T p.I258= | Silent (SNP) | VAF 18/129 reads (14%) | catalogued as COSV58504664, COSV58526290; called by muse, mutect2, varscan2
- PEG3 | c.4614C>T p.A1538= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as COSV55637556, COSV55653069; called by muse, mutect2, varscan2
- PES1 | c.426C>T p.F142= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV58829225, COSV58829664; called by muse, mutect2, varscan2
- PHF21B | c.1384C>T p.L462= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as COSV57561605; called by muse, mutect2, varscan2
- PLXNA4 | c.3261G>A p.E1087= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV58155758; called by muse, mutect2, varscan2
- PLXNA4 | c.2727C>T p.I909= | Silent (SNP) | VAF 47/139 reads (34%) | catalogued as rs778242782, COSV58155771; called by muse, mutect2, varscan2
- POM121C | c.3312C>T p.T1104= (on ENST00000607367; = p.T862= on NM_001099415.3) | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as rs781799072, COSV99993128; called by muse, mutect2
- PPP1R2 | c.192T>C p.G64= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as COSV60498459; called by muse, mutect2, varscan2
- PPP4R4 | c.417C>T p.L139= | Silent (SNP) | VAF 76/159 reads (48%) | catalogued as COSV58557670; called by muse, mutect2, varscan2
- PRICKLE2 | c.2388C>T p.S796= (on ENST00000295902; = p.S740= on NM_198859.4) | Silent (SNP) | VAF 35/41 reads (85%) | catalogued as rs867670809, COSV55763264; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRSS58 | c.138C>T p.I46= | Silent (SNP) | VAF 41/131 reads (31%) | catalogued as COSV73488826; called by muse, mutect2, varscan2
- PSG11 | c.535C>T p.L179= | Silent (SNP) | VAF 214/348 reads (61%) | catalogued as rs1464775002, COSV60457505; called by muse, mutect2, varscan2
- PSG6 | c.702C>T p.L234= | Silent (SNP) | VAF 78/317 reads (25%) | catalogued as COSV51836912; called by muse, mutect2, varscan2
- PTPN23 | c.4890C>T p.L1630= | Silent (SNP) | VAF 66/75 reads (88%) | catalogued as COSV55547858; called by muse, varscan2
- PTPN4 | c.1368C>T p.T456= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV99751559; called by muse, mutect2, varscan2
- PTX4 | c.954C>T p.T318= (on ENST00000447419 / NM_001328608.2; = p.T313= on NM_001013658.1) | Silent (SNP) | VAF 54/116 reads (47%) | catalogued as rs752932855, COSV53519328; called by muse, mutect2, varscan2
- QSOX1 | c.1653C>T p.A551= | Silent (SNP) | VAF 196/203 reads (97%) | catalogued as COSV62581496; called by muse, mutect2, varscan2
- QTRT2 | c.270A>C p.S90= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV55561569; called by muse, mutect2, varscan2
- RASA3 | c.2205C>T p.S735= | Silent (SNP) | VAF 38/62 reads (61%) | catalogued as rs1439222663, COSV61872504; called by muse, mutect2, varscan2
- RFXANK | c.30C>T p.L10= | Silent (SNP) | VAF 178/318 reads (56%) | catalogued as COSV50770718; called by muse, mutect2, varscan2
- RP1 | c.1380G>A p.K460= | Silent (SNP) | VAF 31/59 reads (53%) | catalogued as CM1312868, COSV55125083; called by muse, mutect2, varscan2
- RPGR | c.2806C>T p.L936= (on ENST00000339363 / NM_001367249.1; = p.L731= on NM_000328.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/24 reads (100%) | catalogued as COSV58839409; called by muse, mutect2, varscan2
- RSKR | c.573G>T p.L191= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as COSV56383646; called by muse, varscan2
- RSPH1 | c.675C>T p.P225= | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as COSV52320904; called by muse, mutect2, varscan2
- RXFP1 | c.639T>A p.I213= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as COSV57055745; called by muse, mutect2, varscan2
- SCN10A | c.4383C>T p.P1461= | Silent (SNP) | VAF 100/109 reads (92%) | catalogued as COSV71861458; called by muse, mutect2, varscan2
- SCN5A | c.1272C>T p.I424= | Silent (SNP) | VAF 47/53 reads (89%) | catalogued as rs267599794; ClinVar: likely benign; called by muse, mutect2, varscan2
- SELENOP | c.456C>T p.S152= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV62793827; called by muse, mutect2, varscan2
- SELENOP | c.168A>G p.Q56= | Silent (SNP) | VAF 46/126 reads (37%) | catalogued as COSV72484773; called by muse, mutect2, varscan2
- SERPINB11 | c.1119C>T p.F373= | Silent (SNP) | VAF 76/89 reads (85%) | catalogued as COSV66957716; called by muse, mutect2
- SHANK2 | c.3453G>A p.R1151= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as COSV53587231; called by muse, mutect2, varscan2
- SHROOM3 | c.411G>A p.R137= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV56038108; called by muse, mutect2, varscan2
- SLC1A7 | c.237C>T p.S79= | Silent (SNP) | VAF 21/21 reads (100%) | catalogued as COSV65196022; called by muse, mutect2, varscan2
- SLC26A7 | c.1167C>T p.F389= | Silent (SNP) | VAF 37/133 reads (28%) | catalogued as rs781639714, COSV52586035; called by muse, mutect2, varscan2
- SLC28A1 | c.834C>T p.S278= | Silent (SNP) | VAF 88/218 reads (40%) | catalogued as rs370744094; called by muse, varscan2
- SLC37A2 | c.282C>T p.F94= | Silent (SNP) | VAF 9/9 reads (100%) | catalogued as COSV53524982; called by muse, mutect2, varscan2
- SLC4A1 | c.1353C>T p.F451= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs770941832, COSV52260152; called by muse, mutect2, varscan2
- SLC9A8 | c.459C>T p.S153= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as rs1178856879, COSV100846233, COSV64290966; called by muse, mutect2
- SLCO1B3 | c.306C>T p.L102= | Silent (SNP) | VAF 53/110 reads (48%) | catalogued as COSV53944918; called by muse, mutect2, varscan2
- SMOC1 | c.864G>A p.V288= | Silent (SNP) | VAF 56/106 reads (53%) | catalogued as COSV62763098; called by muse, mutect2, varscan2
- SSTR2 | c.861C>T p.T287= | Silent (SNP) | VAF 92/101 reads (91%) | catalogued as COSV59535950; called by muse, varscan2
- SSTR4 | c.342C>T p.F114= | Silent (SNP) | VAF 80/148 reads (54%) | catalogued as rs767915860, COSV54797472, COSV54798666; called by muse, mutect2, varscan2
- ST14 | c.948G>A p.L316= | Silent (SNP) | VAF 78/121 reads (64%) | catalogued as COSV104377653, COSV53836558; called by muse, mutect2, varscan2
- SUPT3H | c.606A>G p.L202= (on ENST00000371460 / NM_181356.3; = p.L191= on NM_003599.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 109/184 reads (59%) | catalogued as COSV60949631; called by muse, varscan2
- TENM1 | c.4243C>T p.L1415= | Silent (SNP) | VAF 55/58 reads (95%) | catalogued as COSV100950867, COSV64441145; called by muse, mutect2, varscan2
- TFAP2C | c.1080A>G p.K360= | Silent (SNP) | VAF 41/101 reads (41%) | catalogued as COSV52372932; called by muse, mutect2, varscan2
- TINAG | c.840C>T p.N280= | Silent (SNP) | VAF 64/103 reads (62%) | catalogued as COSV52514058; called by muse, mutect2, varscan2
- TLR2 | c.1909A>C p.R637= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV52607874; called by muse, mutect2, varscan2
- TMEM181 | c.81C>T p.Y27= | Silent (SNP) | VAF 46/51 reads (90%) | catalogued as COSV65565593; called by muse, mutect2, varscan2
- TMEM30A | c.1011C>T p.F337= | Silent (SNP) | VAF 27/29 reads (93%) | catalogued as COSV57876821; called by muse, mutect2, varscan2
- TMPRSS6 | c.585C>T p.I195= | Silent (SNP) | VAF 39/92 reads (42%) | catalogued as COSV100696199; called by muse, mutect2, varscan2
- TPCN1 | c.1224G>A p.L408= | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as COSV59239306; called by muse, mutect2, varscan2
- TPO | c.918G>A p.G306= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV61099336; called by muse, mutect2, varscan2
- TRBV28 | c.99G>A p.R33= | Silent (SNP) | VAF 20/69 reads (29%) | called by muse, mutect2, varscan2
- TRHDE | c.2535G>A p.R845= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV53848210; called by muse, mutect2, varscan2
- TRHDE | c.3045C>T p.F1015= | Silent (SNP) | VAF 32/51 reads (63%) | catalogued as COSV53842088, COSV53857232; called by muse, mutect2, varscan2
- TRIM68 | c.1239C>T p.I413= | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as COSV56169887; called by muse, mutect2, varscan2
- TRPC3 | c.2523T>A p.I841= (on ENST00000379645 / NM_001366479.2; = p.I768= on NM_003305.2) | Silent (SNP) | VAF 40/79 reads (51%) | catalogued as COSV53380357; called by muse, mutect2, varscan2
- TRPC4 | c.2043G>A p.K681= | Silent (SNP) | VAF 60/87 reads (69%) | catalogued as COSV59015024; called by muse, mutect2, varscan2
- TTN | c.83667C>T p.I27889= (on ENST00000591111; = p.I20465= on NM_003319.4) | Silent (SNP) | VAF 42/85 reads (49%) | catalogued as rs780772770, COSV59926765; called by muse, mutect2, varscan2
- TTN | c.47802C>T p.I15934= (on ENST00000591111; = p.I8510= on NM_003319.4) | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs751888727, COSV60299185; called by muse, mutect2, varscan2
- TTN | c.24504C>T p.I8168= (on ENST00000591111; = p.I7241= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/82 reads (50%) | catalogued as COSV60299217; called by muse, mutect2, varscan2
- TTN | c.24234G>A p.K8078= (on ENST00000591111; = p.K7151= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV60299227; called by muse, mutect2, varscan2
- TTN | c.450C>T p.F150= | Silent (SNP) | VAF 94/190 reads (49%) | catalogued as rs764467407, COSV60299246; called by muse, mutect2, varscan2
- VARS1 | c.3342C>T p.I1114= | Silent (SNP) | VAF 310/498 reads (62%) | catalogued as COSV63305059; called by muse, mutect2, varscan2
- VAT1L | c.270G>A p.G90= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as COSV56826967; called by muse, mutect2, varscan2
- VAT1L | c.1197G>A p.G399= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as COSV56826975; called by muse, mutect2, varscan2
- VIPAS39 | c.903C>T p.I301= | Silent (SNP) | VAF 52/113 reads (46%) | catalogued as COSV58941772; called by muse, mutect2, varscan2
- XIRP1 | c.126C>T p.F42= | Silent (SNP) | VAF 36/38 reads (95%) | catalogued as COSV61140682; called by muse, mutect2, varscan2
- XPO6 | c.1903T>C p.L635= | Silent (SNP) | VAF 46/119 reads (39%) | catalogued as COSV58970752; called by muse, mutect2, varscan2
- XYLT1 | c.2511C>T p.F837= | Silent (SNP) | VAF 39/100 reads (39%) | catalogued as COSV54476086; called by muse, mutect2, varscan2
- ZNF304 | c.1197C>T p.F399= | Silent (SNP) | VAF 26/47 reads (55%) | catalogued as COSV56586150, COSV99988546; called by muse, mutect2, varscan2
- ZNF398 | c.1680C>T p.I560= (on ENST00000475153 / NM_170686.3; = p.I389= on NM_020781.4) | Silent (SNP) | VAF 54/220 reads (25%) | catalogued as COSV60066530; called by muse, mutect2, varscan2
- ZNF432 | c.1767A>G p.Q589= | Silent (SNP) | VAF 58/92 reads (63%) | catalogued as COSV55418231; called by muse, mutect2, varscan2
- ZNF496 | c.858C>T p.L286= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as COSV54173938; called by muse, mutect2, varscan2
- ZNF831 | c.2409G>A p.Q803= | Silent (SNP) | VAF 40/76 reads (53%) | catalogued as COSV64044588; called by muse, mutect2
- ZSCAN5A | c.486C>T p.S162= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs781265590, COSV54231171; called by muse, mutect2, varscan2
- BMP1 | c.2108-611A>G | Intron (SNP) | VAF 96/182 reads (53%) | catalogued as COSV100110201; called by muse, mutect2, varscan2
- DIDO1 | c.1588+66_1588+76del | Intron (DEL) | VAF 42/111 reads (38%) | called by mutect2, pindel, varscan2
- DSCR4 | n.404T>A | RNA (SNP) | VAF 53/118 reads (45%) | catalogued as COSV60301677; called by muse, mutect2, varscan2
- EI24P4 | n.877T>A | RNA (SNP) | VAF 147/498 reads (30%) | called by muse, mutect2, varscan2
- FGG | c.-1C>T | 5'UTR (SNP) | VAF 9/31 reads (29%) | catalogued as COSV100272112; called by muse, mutect2, varscan2
- FRMPD2 | c.-2G>A | 5'UTR (SNP) | VAF 89/98 reads (91%) | catalogued as COSV100951421; called by muse, mutect2, varscan2
- GCNT2 | c.926-34754_926-34750dup | Intron (INS) | VAF 95/177 reads (54%) | called by mutect2, pindel, varscan2
- MIR515-1 | n.19C>T | RNA (SNP) | VAF 27/46 reads (59%) | called by muse, mutect2, varscan2
- MORF4 | n.927G>A | RNA (SNP) | VAF 8/25 reads (32%) | catalogued as rs1400046357; called by muse, mutect2, varscan2
- PHF20 | c.341-3018C>T | Intron (SNP) | VAF 29/49 reads (59%) | catalogued as rs768780469; called by muse, mutect2, varscan2
- PLCE1 | c.1207-42932G>A | Intron (SNP) | VAF 96/110 reads (87%) | catalogued as COSV53357028, COSV99597524; called by muse, mutect2, varscan2
- SERPINA13P | n.785G>A | RNA (SNP) | VAF 98/236 reads (42%) | catalogued as rs749292252; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-51546C>T | Intron (SNP) | VAF 9/29 reads (31%) | catalogued as rs758196707, COSV101043796, COSV67442715; called by muse, mutect2, varscan2
- SPTB | c.6345+2956C>T | Intron (SNP) | VAF 126/300 reads (42%) | catalogued as COSV100731205; called by muse, mutect2, varscan2
- SSPOP | n.6430G>A | RNA (SNP) | VAF 62/164 reads (38%) | catalogued as COSV50489132; called by muse, mutect2, varscan2
- TTN | c.10360+4994A>T | Intron (SNP) | VAF 24/68 reads (35%) | catalogued as COSV100633017; called by muse, mutect2, varscan2
- TTN | c.10303+2297G>A | Intron (SNP) | VAF 40/95 reads (42%) | catalogued as rs1408667459, COSV59903105; called by muse, mutect2, varscan2
- UNC5D | c.104-4782G>A | Intron (SNP) | VAF 50/80 reads (63%) | catalogued as COSV99779228; called by muse, mutect2, varscan2
- UVSSA | c.*9806C>T | 3'UTR (SNP) | VAF 47/82 reads (57%) | catalogued as rs1167357104, COSV61351526; called by muse, mutect2, varscan2
